Somatic mutation profile of tumor specimen TCGA-PE-A5DD-01A (aliquot TCGA-PE-A5DD-01A-12D-A27P-09) from TCGA case TCGA-PE-A5DD, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 64.8 years (23,686 days).
Specimen TCGA-PE-A5DD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3cfbb463-450a-46a2-91e6-4deb0b390fc4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PE-A5DD-10A (Blood Derived Normal), aliquot TCGA-PE-A5DD-10A-01D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98832672-1ac1-4849-a61e-c3bd0e202660

The open-access MAF lists 55 somatic variants for this specimen: 41 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 13, Frame Shift Del 2, In Frame Ins 1, In Frame Del 1, Splice Site 1, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 19/40 reads (48%) | hotspot (GDC flag); catalogued as rs587780784, CM022775, COSV55727261; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 11/21 reads (52%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AMPD3 | c.1681T>C p.Y561H (on ENST00000396553 / NM_001025389.2; = p.Y570H on NM_000480.3) | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as COSV101158215; called by muse, mutect2, varscan2
- ARHGAP32 | c.3792G>A p.M1264I (on ENST00000310343 / NM_001378025.1; = p.M915I on NM_014715.4) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100088598; called by muse, mutect2, varscan2
- CATSPER4 | c.1376C>G p.S459C | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV100128474; called by muse, mutect2, varscan2
- CCDC92 | c.87C>A p.S29R | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99435765; called by muse, mutect2, varscan2
- CHSY1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as COSV99574103; called by muse, mutect2, varscan2
- DENND2A | c.2063G>A p.R688Q | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs755191369, COSV52053692; called by muse, mutect2, varscan2
- FDPS | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV99430137; called by muse, mutect2, varscan2
- FILIP1 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1256647931, COSV52738472; called by muse, mutect2, varscan2
- FOXO4 | c.1186C>G p.L396V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.232); catalogued as COSV100447008; called by muse, mutect2, varscan2
- HPN | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs751620154, COSV52886587; called by mutect2, varscan2
- IFIT1 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100878743; called by muse, mutect2
- KIAA0513 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.024); catalogued as rs751384535, COSV99261152; called by muse, mutect2, varscan2
- LCMT2 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); catalogued as COSV99980175; called by muse, mutect2, varscan2
- LIMK1 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as COSV100283349; called by muse, mutect2
- LMNA | c.1498G>T p.A500S | Missense Mutation (SNP) | VAF 5/111 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as rs996785044, COSV100738779; called by muse, mutect2
- MIA2 | c.365C>A p.T122K | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as COSV99698010; called by muse, mutect2, varscan2
- MUC4 | c.15856C>A p.R5286S (on ENST00000463781 / NM_018406.7; = p.R1050S on NM_004532.6) | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); catalogued as COSV100205711; called by muse, mutect2, varscan2
- NKRF | c.1154A>G p.H385R | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.084); catalogued as COSV58663209; called by muse, mutect2, varscan2
- OR52B4 | c.500G>C p.R167T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV101281597; called by muse, varscan2
- OR8I2 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs749949853, COSV56168001, COSV56168420; called by muse, mutect2, varscan2
- P3H1 | c.1406C>T p.S469F | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99355431; called by muse, mutect2, varscan2
- PHACTR3 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV100732963; called by muse, mutect2, varscan2
- PPP4R3A | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.792); catalogued as COSV61504208; called by muse, mutect2, varscan2
- PRAG1 | c.1036G>A p.G346S | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated, low confidence (0.5); PolyPhen probably damaging (0.934); catalogued as rs928953570, COSV100422552; called by muse, mutect2, varscan2
- PRDM2 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.901); catalogued as COSV99342375; called by muse, mutect2, varscan2
- PTPRK | c.2599A>G p.I867V (on ENST00000368215 / NM_001291984.2; = p.I868V on NM_002844.4) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.641); catalogued as rs375206155; called by muse, mutect2, varscan2
- SRSF1 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.969); catalogued as COSV99365446; called by muse, mutect2, varscan2
- TBCCD1 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100112070; called by muse, mutect2, varscan2
- TPTE | c.1540G>A p.E514K (on ENST00000618007 / NM_199261.4; = p.E496K on NM_199259.4) | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs751475912; called by muse, mutect2, varscan2
- WNT16 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV55975614; called by muse, mutect2, varscan2
- XIRP2 | c.839C>T p.P280L (on ENST00000628543; = p.P455L on NM_152381.6) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1444974219, COSV54737191; called by muse, mutect2, varscan2
- ZNF334 | c.1438C>A p.Q480K | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.124); catalogued as COSV100749156; called by muse, mutect2, varscan2
- ZNF507 | c.1654G>A p.D552N | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100322024; called by muse, mutect2, varscan2
- CFAP126 | c.134_136dup p.D45_R46insH | In Frame Ins (INS) | VAF 21/54 reads (39%) | called by mutect2, pindel, varscan2
- IGKV1D-16 | c.293G>T p.S98I | Missense Mutation (SNP) | VAF 72/177 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- RBP3 | c.3246-1G>A p.X1082_splice | Splice Site (SNP) | VAF 34/94 reads (36%) | called by muse, mutect2, varscan2
- TNR | c.2690_2692del p.S897del | In Frame Del (DEL) | VAF 18/80 reads (23%) | called by mutect2, pindel, varscan2
- USF3 | c.1952_1953del p.T651Ifs*81 | Frame Shift Del (DEL) | VAF 20/78 reads (26%) | called by mutect2, pindel, varscan2
- ZMYM3 | c.3660del p.F1220Lfs*34 | Frame Shift Del (DEL) | VAF 27/93 reads (29%) | called by mutect2, pindel, varscan2
- AKAP13 | c.6591G>A p.K2197= (on ENST00000394518 / NM_007200.5; = p.K2201= on NM_006738.6) | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs998000681, COSV100774250; called by muse, mutect2, varscan2
- ANXA5 | c.15C>T p.L5= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs1287668029, COSV99634584; called by muse, mutect2, varscan2
- APBB2 | c.2172G>T p.P724= (on ENST00000295974 / NM_001166050.2; = p.P725= on NM_004307.2) | Silent (SNP) | VAF 42/107 reads (39%) | catalogued as rs202161633, COSV99923773; called by muse, mutect2, varscan2
- BIRC6 | c.8463T>A p.T2821= | Silent (SNP) | VAF 33/119 reads (28%) | catalogued as COSV101428539; called by muse, mutect2, varscan2
- COG3 | c.567G>T p.L189= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs1310177480, COSV100596682; called by muse, mutect2, varscan2
- CSRNP3 | c.66G>A p.R22= | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as COSV100086122; called by muse, mutect2
- DUOX2 | c.1902C>G p.L634= | Silent (SNP) | VAF 25/43 reads (58%) | catalogued as COSV101199845; called by muse, mutect2, varscan2
- FAM47B | c.567G>A p.P189= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as COSV61454454; called by muse, mutect2, varscan2
- FRMPD4 | c.51G>A p.T17= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs753155651, COSV66213341, COSV66213803; called by muse, mutect2, varscan2
- NUP155 | c.27G>A p.A9= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs1244442616, COSV51527269; called by muse, mutect2, varscan2
- PCSK2 | c.33G>A p.A11= | Silent (SNP) | VAF 33/60 reads (55%) | catalogued as COSV99360275; called by muse, mutect2, varscan2
- SHANK1 | c.1788C>G p.V596= | Silent (SNP) | VAF 38/110 reads (35%) | catalogued as COSV99521708; called by muse, mutect2, varscan2
- SIGLEC1 | c.3513G>A p.A1171= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as rs984548764, COSV99169852; called by muse, mutect2, varscan2
- MUC2 | chr11:1099196 C>A | 3'Flank (SNP) | VAF 39/137 reads (28%) | catalogued as rs886821899; called by muse, mutect2, varscan2
